Somatic mutation profile of tumor specimen TCGA-DD-AADU-01A (aliquot TCGA-DD-AADU-01A-11D-A40R-10) from TCGA case TCGA-DD-AADU, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 60.1 years (21,940 days).
Specimen TCGA-DD-AADU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bdef5861-1c6e-4d78-a898-a1133a43ee20.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AADU-10A (Blood Derived Normal), aliquot TCGA-DD-AADU-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd8412ef-bec8-4796-aee7-4b4e2441dd8c

The open-access MAF lists 101 somatic variants for this specimen: 78 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 21, Nonsense Mutation 3, Frame Shift Del 2, Intron 1, Splice Region 1, Translation Start Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 93/160 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- ACTC1 | c.643A>T p.K215* | Nonsense Mutation (SNP) | VAF 68/121 reads (56%) | catalogued as COSV99291970; called by muse, mutect2, varscan2
- ACVR2A | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 78/279 reads (28%) | catalogued as COSV54018614; called by muse, mutect2, varscan2
- ALB | c.520T>C p.Y174H | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.912); catalogued as COSV99891747; called by muse, mutect2, varscan2
- ATP2B2 | c.2146G>T p.V716F (on ENST00000352432; = p.V682F on NM_001683.5) | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100660173; called by muse, mutect2, varscan2
- AXDND1 | c.2691T>A p.F897L | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100858525; called by muse, mutect2, varscan2
- BRINP3 | c.727C>A p.L243I | Missense Mutation (SNP) | VAF 52/73 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV100819091; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1697A>G p.H566R | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100575603; called by muse, mutect2, varscan2
- CLUL1 | c.522T>A p.D174E | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.323); catalogued as COSV100621010; called by muse, mutect2, varscan2
- CNOT4 | c.882A>T p.I294= (on ENST00000315544 / NM_001190848.1; = p.I291= on NM_013316.4) | Splice Region (SNP) | VAF 29/84 reads (35%) | catalogued as COSV100211852; called by muse, mutect2, varscan2
- COL6A1 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.102); catalogued as rs765826390, COSV62615268; called by muse, mutect2, varscan2
- DMKN | c.511C>A p.P171T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV100303762; called by muse, mutect2, varscan2
- DOCK7 | c.6373T>G p.C2125G (on ENST00000635253 / NM_001367561.1; = p.C2094G on NM_033407.3) | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV99225102; called by muse, mutect2, varscan2
- DSPP | c.302A>T p.N101I | Missense Mutation (SNP) | VAF 119/313 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.238); catalogued as COSV99217620; called by muse, mutect2, varscan2
- DTNB | c.1285A>T p.N429Y | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV56472138, COSV99977630; called by muse, mutect2, varscan2
- DYNAP | c.80T>C p.M27T (on ENST00000321600; = p.M1? on NM_173629.3) | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100391786; called by muse, mutect2, varscan2
- DYNC2H1 | c.12527C>T p.P4176L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100519039; called by muse, mutect2, varscan2
- EEF1D | c.239T>C p.L80P | Missense Mutation (SNP) | VAF 133/253 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99435077; called by muse, mutect2, varscan2
- EXT2 | c.1174G>C p.A392P (on ENST00000343631; = p.A425P on NM_000401.3) | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0.125); catalogued as CS063301, COSV100640642; called by muse, mutect2, varscan2
- FCN1 | c.388G>T p.G130C | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100878927; called by muse, mutect2, varscan2
- FER1L5 | c.3981G>T p.M1327I (on ENST00000623019; = p.M1300I on NM_001293083.2) | Missense Mutation (SNP) | VAF 63/105 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.437); catalogued as COSV101208887; called by muse, mutect2, varscan2
- FGF23 | c.741C>G p.F247L | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.017); catalogued as COSV52976035, COSV99426566; called by muse, mutect2, varscan2
- GATM | c.452T>C p.L151S | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV101188341; called by muse, mutect2, varscan2
- GFAP | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 64/120 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs146698039; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HELZ | c.1367A>G p.Y456C | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770688528, COSV100698885; called by muse, mutect2, varscan2
- IKZF1 | c.641G>T p.S214I | Missense Mutation (SNP) | VAF 105/262 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV100498546; called by muse, mutect2, varscan2
- KIF17 | c.2044G>T p.A682S | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.018); catalogued as COSV99929365; called by muse, mutect2, varscan2
- KIRREL2 | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99384156; called by muse, mutect2, varscan2
- LAMB2 | c.3469C>T p.R1157C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs747064604, COSV100026320; called by muse, mutect2, varscan2
- MAT1A | c.754A>G p.I252V | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100944470; called by muse, mutect2, varscan2
- MUC16 | c.5276A>T p.D1759V | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.25); catalogued as rs948867743, COSV101200442; called by muse, mutect2, varscan2
- MUC5B | c.12811T>A p.S4271T | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV101500527; called by muse, mutect2, varscan2
- NBEA | c.2497C>A p.P833T | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV100082067; called by muse, varscan2
- NBEA | c.2498C>A p.P833Q | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV100082069; called by muse, varscan2
- NDUFA9 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.1); catalogued as COSV99865811; called by muse, mutect2, varscan2
- NOS1AP | c.368C>A p.S123Y | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100723451; called by muse, mutect2, varscan2
- OR4K1 | c.744T>G p.I248M | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV99579129; called by muse, mutect2, varscan2
- OR51I2 | c.499C>A p.P167T | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100413428; called by muse, mutect2, varscan2
- PANX3 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV52511554; called by muse, mutect2, varscan2
- PCBP1 | c.115A>C p.I39L | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV100340181; called by muse, mutect2, varscan2
- PCLO | c.6175C>G p.L2059V | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100434546; called by muse, mutect2, varscan2
- PNMA8A | c.766C>A p.P256T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.086); catalogued as COSV100562379, COSV58136470; called by muse, mutect2, varscan2
- POPDC3 | c.596T>A p.V199E | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99633895; called by muse, mutect2
- POTEF | c.2463G>T p.Q821H | Missense Mutation (SNP) | VAF 130/231 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.095); catalogued as COSV100665088, COSV62545352; called by muse, mutect2, varscan2
- PSD2 | c.1331G>A p.G444D | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1230507306, COSV99217320; called by muse, mutect2, varscan2
- PSMD12 | c.922C>G p.L308V | Missense Mutation (SNP) | VAF 93/386 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.257); catalogued as COSV100635381; called by muse, mutect2, varscan2
- PTF1A | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 230/630 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV100919596; called by muse, mutect2, varscan2
- PTPN5 | c.1402G>T p.A468S | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100080052; called by muse, mutect2, varscan2
- RBM41 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 108/130 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs756498589, COSV99179806; called by muse, mutect2, varscan2
- RFPL3 | c.214C>A p.H72N (on ENST00000249007 / NM_001098535.1; = p.H43N on NM_006604.2) | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV99967167; called by muse, mutect2
- RGS18 | c.92A>G p.E31G | Missense Mutation (SNP) | VAF 211/964 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV100817841; called by muse, mutect2, varscan2
- RNASE11 | c.419T>C p.V140A | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV100250579; called by muse, varscan2
- SALL3 | c.3661A>T p.N1221Y | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101610024; called by muse, mutect2
- SEC61A1 | c.1357A>G p.I453V | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.105); catalogued as rs1559800207, COSV99684923; called by muse, mutect2, varscan2
- SEMA3E | c.591C>G p.S197R | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV100319031; called by muse, mutect2, varscan2
- SLC5A12 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.506); catalogued as COSV54819309; called by muse, mutect2, varscan2
- SLC8A1 | c.1038A>G p.I346M | Missense Mutation (SNP) | VAF 60/109 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs760339904, COSV60498187; called by muse, mutect2, varscan2
- SLC9C1 | c.610T>A p.L204I | Missense Mutation (SNP) | VAF 88/277 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.061); catalogued as COSV99998292; called by muse, mutect2, varscan2
- SMAD4 | c.383T>C p.V128A | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV61696069; called by muse, mutect2, varscan2
- SMAD9 | c.143A>T p.K48M | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100614854; called by muse, mutect2, varscan2
- TOX | c.287T>A p.L96Q | Missense Mutation (SNP) | VAF 106/301 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV100812922; called by muse, mutect2, varscan2
- TPO | c.334T>C p.S112P | Missense Mutation (SNP) | VAF 61/214 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.327); catalogued as COSV100221615; called by muse, mutect2, varscan2
- TULP4 | c.3587A>G p.N1196S | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100893638; called by muse, mutect2, varscan2
- UBA5 | c.505T>G p.L169V | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV99393304; called by muse, mutect2, varscan2
- UBASH3A | c.189C>A p.D63E | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99369759; called by muse, mutect2, varscan2
- UBR1 | c.4264G>T p.V1422F | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99317521; called by muse, mutect2, varscan2
- UNC13C | c.2939A>T p.Y980F | Missense Mutation (SNP) | VAF 109/185 reads (59%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.985); catalogued as COSV99520112; called by muse, mutect2, varscan2
- XKR7 | c.442T>C p.F148L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV101629279; called by muse, mutect2, varscan2
- ZBED6CL | c.257A>C p.E86A | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV100550574; called by muse, mutect2, varscan2
- ZEB1 | c.568A>T p.K190* | Nonsense Mutation (SNP) | VAF 45/125 reads (36%) | catalogued as COSV100314659; called by muse, mutect2, varscan2
- ZFP42 | c.521A>T p.K174M | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.46); PolyPhen benign (0.048); catalogued as COSV100478993, COSV58819789; called by muse, mutect2, varscan2
- ZNF253 | c.992A>G p.K331R | Missense Mutation (SNP) | VAF 61/118 reads (52%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV100849550; called by muse, mutect2, varscan2
- ZNF347 | c.166A>G p.I56V | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1238297160, COSV100498346; called by muse, mutect2, varscan2
- ZNF7 | c.1428A>C p.K476N | Missense Mutation (SNP) | VAF 74/256 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100295982; called by muse, mutect2, varscan2
- IGHG1 | c.17del p.P6Hfs*32 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | called by mutect2, pindel, varscan2
- OR10G2 | c.677T>G p.I226R | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- RHCG | c.1392del p.M465Wfs*39 | Frame Shift Del (DEL) | VAF 26/126 reads (21%) | called by mutect2, pindel, varscan2
- XKR3 | c.1368G>T p.M456I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.107); called by muse, mutect2
- ADH1A | c.858A>G p.A286= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV99265868; called by muse, mutect2, varscan2
- ATP2B3 | c.96G>T p.A32= | Silent (SNP) | VAF 63/78 reads (81%) | catalogued as rs202115287, COSV99685131; called by muse, mutect2, varscan2
- BACH1 | c.678A>G p.K226= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as COSV99728421; called by muse, mutect2, varscan2
- DDX53 | c.258C>T p.N86= | Silent (SNP) | VAF 113/142 reads (80%) | catalogued as rs778444531, COSV60068691; called by muse, mutect2, varscan2
- FLG | c.9804A>T p.A3268= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as COSV100911792; called by muse, mutect2, varscan2
- GNA13 | c.532C>T p.L178= | Silent (SNP) | VAF 95/363 reads (26%) | catalogued as COSV101457486; called by muse, mutect2, varscan2
- LRRC37A3 | c.564T>C p.D188= | Silent (SNP) | VAF 40/183 reads (22%) | catalogued as COSV100141239; called by muse, mutect2, varscan2
- MAGEL2 | c.2109G>A p.A703= | Silent (SNP) | VAF 52/186 reads (28%) | catalogued as COSV58566865; called by muse, mutect2, varscan2
- MYT1L | c.2775A>T p.S925= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV101217269; called by muse, mutect2, varscan2
- OR4F17 | c.351A>T p.I117= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as COSV100535570; called by mutect2, varscan2
- OR5D14 | c.564T>A p.S188= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV100162483, COSV59455350; called by muse, mutect2, varscan2
- PPP1R1B | c.495C>T p.R165= | Silent (SNP) | VAF 64/119 reads (54%) | catalogued as COSV54202088, COSV99566292; called by muse, mutect2, varscan2
- PRUNE2 | c.6027A>G p.T2009= | Silent (SNP) | VAF 41/114 reads (36%) | catalogued as rs1305786624, COSV100944828; called by muse, mutect2, varscan2
- PUM2 | c.30A>G p.L10= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV100163802; called by muse, mutect2, varscan2
- RAD18 | c.204A>T p.T68= | Silent (SNP) | VAF 31/129 reads (24%) | catalogued as COSV99368630; called by muse, mutect2, varscan2
- RFX7 | c.1446G>A p.L482= (on ENST00000559447 / NM_001368074.1; = p.L579= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs372457778; called by muse, mutect2, varscan2
- RNF113A | c.378A>G p.K126= | Silent (SNP) | VAF 18/23 reads (78%) | catalogued as COSV101007077; called by muse, mutect2, varscan2
- SLC7A7 | c.1365C>A p.P455= | Silent (SNP) | VAF 140/198 reads (71%) | catalogued as COSV53538031; called by muse, mutect2, varscan2
- TBXAS1 | c.1572T>C p.N524= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV99694171; called by muse, mutect2, varscan2
- USP6 | c.1002C>T p.N334= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs769234796, COSV51474899; called by muse, mutect2, varscan2
- ZCCHC9 | c.612A>G p.K204= | Silent (SNP) | VAF 67/114 reads (59%) | catalogued as COSV99562679; called by muse, mutect2, varscan2
- HAS3 | chr16:69118416 del CGGAAGCATGGTCCGTTCACCAACGC | 3'Flank (DEL) | VAF 47/104 reads (45%) | called by mutect2, pindel, varscan2
- PKD2L2 | c.*18-2237del | Intron (DEL) | VAF 76/240 reads (32%) | called by mutect2, pindel, varscan2
